Somatic mutation profile of tumor specimen MBCProject_1001_T1B_WES (aliquot MBCProject_1001_T1B_WES_1) from CMI case MBCProject_1001, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 41.2 years (15,057 days).
Specimen MBCProject_1001_T1B_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 013e0ce3-8642-49cb-a015-898cf3e3f5b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1001_SALIVA (Saliva), aliquot MBCProject_1001_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14b7873a-74cc-4b3f-a872-228e791c5826

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, 3'UTR 1, 5'UTR 1, Splice Site 1, Frame Shift Del 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.393del p.N131Kfs*39 | Frame Shift Del (DEL) | VAF 20/119 reads (17%) | catalogued as rs1567554408, COSV52891063, COSV52938317, COSV53696738, COSV53770947; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- C16orf70 | c.907A>C p.K303Q | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0.323); catalogued as rs1228833407; called by muse, mutect2
- C18orf25 | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs1162042835; called by muse, mutect2, varscan2
- FHOD3 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57184994; called by mutect2, varscan2
- HLX | c.952G>C p.A318P | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65044861; called by muse, mutect2
- KALRN | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as rs141093471; called by muse, mutect2
- NYX | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as rs766445016; called by muse, mutect2, varscan2
- PCDHGB6 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as rs759433257, COSV53899866; called by muse, mutect2, varscan2
- TRIM37 | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 25/150 reads (17%) | catalogued as COSV51881421; called by muse, mutect2, varscan2
- WDR5 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100681654; called by muse, mutect2
- WNT11 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1247453401, COSV100490344; called by muse, mutect2, varscan2
- ACOD1 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANAPC13 | c.127A>G p.N43D | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2
- LIM2 | c.414G>C p.W138C (on ENST00000596399 / NM_001161748.2; = p.W180C on NM_030657.4) | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MUC19 | c.32+1G>T p.X11_splice | Splice Site (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2
- SYNPO2 | c.63G>T p.L21F | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UBR5 | c.26A>G p.H9R | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2
- ADGRD1 | c.1527C>T p.Y509= | Silent (SNP) | VAF 6/87 reads (7%) | called by muse, mutect2
- CCNJL | c.39G>A p.S13= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as rs576590793, COSV99979151; called by muse, mutect2, varscan2
- DNAJC11 | c.996G>T p.G332= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV53786716; called by muse, mutect2, varscan2
- NRG2 | c.939C>T p.A313= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as rs774819017, COSV99179925; called by muse, mutect2, varscan2
- KIF13B | c.-13C>T | 5'UTR (SNP) | VAF 16/276 reads (6%) | catalogued as rs1333141906, COSV101580689; called by muse, mutect2
- RBM3 | chrX:48574621 G>T | 5'Flank (SNP) | VAF 45/171 reads (26%) | called by muse, mutect2, varscan2
- RGS7 | c.*39C>T | 3'UTR (SNP) | VAF 31/103 reads (30%) | called by muse, mutect2, varscan2
